Somatic mutation profile of tumor specimen TCGA-VQ-AA6I-01A (aliquot TCGA-VQ-AA6I-01A-11D-A410-08) from TCGA case TCGA-VQ-AA6I, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 68.7 years (25,091 days).
Specimen TCGA-VQ-AA6I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a308135-5221-4e7c-a992-3e69d78f4383.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6I-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6I-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21b7879-944a-4be3-875d-4ac7ea315349

The open-access MAF lists 107 somatic variants for this specimen: 84 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Frame Shift Del 8, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 2, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 11/16 reads (69%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as rs1222856535, COSV100748024; called by muse, mutect2, varscan2
- ACAN | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100718727; called by muse, mutect2, varscan2
- ACVR2A | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99604772; called by muse, mutect2, varscan2
- AMD1 | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100924507; called by muse, mutect2, varscan2
- ARHGAP36 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 115/163 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs974805626, COSV52266263, COSV52274371; called by muse, mutect2, varscan2
- ASB10 | c.914G>A p.G305D (on ENST00000420175 / NM_001142459.2; = p.G290D on NM_080871.4) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745358274, COSV99318787; called by muse, mutect2, varscan2
- BTN3A3 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV99764962; called by muse, mutect2, varscan2
- CCKBR | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV58106335; called by muse, mutect2, varscan2
- CCT6B | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1190984575, COSV100030866; called by muse, mutect2, varscan2
- CNTN6 | c.1953A>T p.E651D | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as COSV63172015; called by muse, varscan2
- COL11A1 | c.3865G>T p.A1289S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1212241628, COSV100617510, COSV62189537; called by muse, mutect2, varscan2
- CREBBP | c.4805G>A p.R1602H | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1274540523, COSV52140014, COSV99272523; called by muse, mutect2, varscan2
- CTDSPL | c.481C>T p.L161F (on ENST00000273179 / NM_001008392.2; = p.L150F on NM_005808.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99828873; called by mutect2, varscan2
- CYP7B1 | c.884C>A p.A295E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100042405; called by muse, mutect2, varscan2
- DLEU7 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1280474400, COSV68546525; called by muse, mutect2, varscan2
- ELAPOR2 | c.2320T>G p.L774V (on ENST00000450689 / NM_001142749.3; = p.L607V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV51888180; called by muse, mutect2, varscan2
- EVPL | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs766658055, COSV56910249; called by muse, mutect2, varscan2
- EZH1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV101331409; called by muse, mutect2, varscan2
- FILIP1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs147080592; called by muse, mutect2, varscan2
- FMNL3 | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs773386245, COSV99526666; called by muse, mutect2, varscan2
- FUT10 | c.442C>G p.H148D | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243571063, COSV100161604, COSV59453570; called by muse, mutect2, varscan2
- GPR141 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV100550377; called by muse, mutect2, varscan2
- GTF3C3 | c.1831+1G>C p.X611_splice | Splice Site (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99826834; called by muse, mutect2, varscan2
- H4C13 | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV100137994; called by muse, mutect2, varscan2
- HPSE2 | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); catalogued as COSV100986027, COSV100986121; called by muse, mutect2, varscan2
- HS6ST1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs377319981; called by muse, varscan2
- IFI16 | c.1698A>C p.E566D (on ENST00000295809 / NM_001364867.2; = p.E510D on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as rs777391755, COSV55530534; called by muse, mutect2, varscan2
- IRGC | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs760423917, COSV99746431; called by muse, varscan2
- KNDC1 | c.4066del p.L1356Wfs*109 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs1357824752; called by mutect2, pindel, varscan2
- LRIG2 | c.2146C>G p.Q716E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as rs1206186650, COSV100743536; called by muse, mutect2, varscan2
- LRIT1 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as rs370643022; called by muse, mutect2, varscan2
- LRP1B | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs921851032, COSV67214705; called by muse, mutect2, varscan2
- LRP5 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs748395267, COSV53714552; called by muse, mutect2, varscan2
- MAGI2 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100834403, COSV100835476; called by muse, mutect2
- MAP1A | c.2341_2342insGTA p.A781delinsGT | In Frame Ins (INS) | VAF 6/21 reads (29%) | catalogued as COSV100288953; called by mutect2, pindel, varscan2
- MDGA2 | c.2221C>T p.R741W (on ENST00000399232 / NM_001113498.2; = p.R443W on NM_182830.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.944); catalogued as rs1345693697, COSV100637625; called by muse, mutect2, varscan2
- MED13L | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99929512; called by muse, mutect2, varscan2
- MIPEP | c.1340A>G p.D447G | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101193184; called by muse, mutect2, varscan2
- MKI67 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 33/146 reads (23%) | catalogued as rs142132992; called by muse, mutect2, varscan2
- MRC2 | c.2162A>G p.H721R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.832); catalogued as COSV57636141, COSV57639555; called by muse, mutect2, varscan2
- MRGBP | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65111812; called by muse, mutect2, varscan2
- MROH2B | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1407999857, COSV68182448; called by muse, mutect2, varscan2
- MRPL44 | c.735del p.K246Rfs*35 | Frame Shift Del (DEL) | VAF 25/111 reads (23%) | catalogued as COSV51314593; called by mutect2, pindel, varscan2
- MS4A13 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1380314044, COSV100981158; called by muse, mutect2, varscan2
- NAA11 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1374492628, COSV54516499; called by muse, mutect2, varscan2
- NMRK1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100738046; called by muse, mutect2, varscan2
- NUP214 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 98/244 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs371523799; called by muse, mutect2, varscan2
- OR2F2 | c.509C>G p.T170S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs376743624, COSV101283801; called by muse, mutect2, varscan2
- OR4C16 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1404669415, COSV58940425, COSV58941301, COSV58942700; called by muse, mutect2, varscan2
- OR51B6 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100971659; called by muse, mutect2, varscan2
- OSBPL5 | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99720610; called by muse, mutect2, varscan2
- PAK1IP1 | c.219T>G p.I73M | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs778004073, COSV99468599; called by muse, mutect2, varscan2
- PCLO | c.4829G>T p.R1610L | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1390720559, COSV100434794; called by muse, mutect2, varscan2
- PDE9A | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569276158, COSV52324939; called by muse, mutect2, varscan2
- PLEC | c.1474C>T p.L492F (on ENST00000322810 / NM_201380.4; = p.L382F on NM_000445.5) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs200260527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R12C | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1374028315, COSV54737381; called by muse, mutect2, varscan2
- PRKACG | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1357672831, COSV99599358; called by muse, mutect2, varscan2
- PRKCI | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99856010; called by muse, mutect2, varscan2
- PSMB3 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs771740744; called by muse, mutect2, varscan2
- PZP | c.1292C>A p.S431* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99738684; called by muse, mutect2, varscan2
- RP1L1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 507/565 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs375440665; called by muse, mutect2, varscan2
- RTCB | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1433322006, COSV53279421, COSV99322313; called by muse, mutect2
- RUSC2 | c.3388G>A p.D1130N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100770793, COSV100770802; called by muse, mutect2, varscan2
- SLC12A9 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51938164, COSV99308003; called by muse, mutect2, varscan2
- SLC39A8 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as rs753110864, COSV100765837; called by muse, mutect2, varscan2
- TDRP | c.265T>G p.W89G | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV60705988; called by muse, mutect2, varscan2
- TM9SF3 | c.1212dup p.V405Cfs*60 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs1271316694; called by mutect2, varscan2
- TRPC6 | c.2103A>C p.E701D | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100723695; called by muse, mutect2, varscan2
- TTN | c.27710G>T p.R9237M (on ENST00000591111; = p.R8310M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | PolyPhen benign (0.086); catalogued as COSV100621304; called by muse, mutect2, varscan2
- USH2A | c.12059C>A p.T4020K | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238747; called by muse, mutect2, varscan2
- VRK2 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100418136; called by muse, mutect2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | catalogued as rs563751025; called by mutect2, varscan2
- ZNF385D | c.61C>A p.R21S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV99875443, COSV99875587; called by muse, mutect2
- ZNF397 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as COSV99735053; called by muse, mutect2, varscan2
- ZNF570 | c.605dup p.N202Kfs*6 | Frame Shift Ins (INS) | VAF 69/174 reads (40%) | catalogued as rs758109083; called by mutect2, varscan2
- ZNF862 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as rs1226967276; called by muse, mutect2
- AMER2 | c.1667_1668del p.Y556* | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.2784_2785del p.N929Pfs*40 | Frame Shift Del (DEL) | VAF 36/142 reads (25%) | called by pindel, varscan2
- IRS2 | c.3995_4012+1del p.X1332_splice | Splice Site (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- LDHA | c.766_767del p.V256Sfs*12 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- PRICKLE3 | c.1157del p.P386Lfs*16 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- WRAP53 | c.893_896del p.R298Lfs*33 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- AC006059.2 | c.432C>T p.A144= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100045752; called by muse, mutect2, varscan2
- ADAM17 | c.822C>G p.G274= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV100176395; called by muse, varscan2
- CALD1 | c.1749G>A p.E583= (on ENST00000361675 / NM_033138.4; = p.E328= on NM_004342.7) | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs976763679, COSV100724421; called by muse, mutect2, varscan2
- CNTNAP4 | c.2785C>T p.L929= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100272378; called by muse, mutect2, varscan2
- DOCK2 | c.4017A>G p.K1339= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV99913957; called by muse, mutect2, varscan2
- DOT1L | c.4407G>A p.P1469= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1313785172, COSV101288738; called by muse, mutect2, varscan2
- EMILIN3 | c.792C>A p.T264= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100182689; called by muse, mutect2, varscan2
- ERCC3 | c.93G>A p.G31= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV99573509; called by muse, mutect2, varscan2
- EYA4 | c.888G>A p.S296= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs768010410, COSV62060689; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ITFG1 | c.120G>A p.E40= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100067937; called by muse, mutect2, varscan2
- KMT2A | c.3942G>A p.P1314= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1555039447, COSV100629332; called by muse, mutect2, varscan2
- MUC16 | c.8511G>T p.L2837= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV101200520; called by muse, mutect2, varscan2
- MUC17 | c.11739C>T p.A3913= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as COSV100074298; called by muse, mutect2, varscan2
- NKPD1 | c.1621C>T p.L541= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100521656; called by muse, mutect2
- OR2F2 | c.510T>A p.T170= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs538779776, COSV101283802; called by muse, mutect2, varscan2
- PCDHA3 | c.288C>T p.C96= | Silent (SNP) | VAF 47/261 reads (18%) | catalogued as rs529252017, COSV65367602, COSV65370261; called by muse, mutect2, varscan2
- RHOXF2 | c.465C>T p.R155= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1556004657, COSV101002773; called by muse, mutect2, varscan2
- SDK1 | c.384C>T p.A128= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs370227347; called by mutect2, varscan2
- SMG5 | c.2904C>T p.G968= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs770497122, COSV99431378; called by muse, mutect2, varscan2
- SYT9 | c.429G>C p.G143= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs756079021, COSV100608674, COSV59617624; called by muse, mutect2, varscan2
- VCX2 | c.324C>T p.S108= | Silent (SNP) | VAF 44/75 reads (59%) | catalogued as rs200914527, COSV100400058, COSV57703709; called by muse, mutect2, varscan2
- ZNF671 | c.1032C>T p.S344= | Silent (SNP) | VAF 34/172 reads (20%) | catalogued as COSV58053741; called by muse, mutect2, varscan2
- KHK | c.210-320T>C | Intron (SNP) | VAF 33/107 reads (31%) | catalogued as COSV99566402; called by muse, mutect2, varscan2
